Somatic mutation profile of tumor specimen TCGA-D9-A6EC-06A (aliquot TCGA-D9-A6EC-06A-11D-A30X-08) from TCGA case TCGA-D9-A6EC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 60.5 years (22,106 days).
Specimen TCGA-D9-A6EC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11bb64c3-27fb-4c93-8f3d-fda640726262.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A6EC-10A (Blood Derived Normal), aliquot TCGA-D9-A6EC-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d907d15f-5ae8-4372-94c2-d3df8137c224

The open-access MAF lists 5,051 somatic variants for this specimen: 3,463 protein-altering or splice-affecting, 1,477 silent, 111 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,213, Silent 1,477, Nonsense Mutation 159, Intron 51, Splice Site 43, Splice Region 35, RNA 34, 5'Flank 8, 5'UTR 7, 3'UTR 6, Frame Shift Del 5, 3'Flank 5.

Variants (750 of 5,051; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs767586362, COSV56753117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.2758C>T p.Q920* | Nonsense Mutation (SNP) | VAF 45/83 reads (54%) | catalogued as rs387906845, CM122484, COSV61371886; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1575G>T p.L525F (on ENST00000288602 / NM_001374244.1; = p.L485F on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs180177036, CM060880, COSV56396779; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFTR | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs556880586, CM162714, COSV50041108; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CNOT9 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 47/212 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as rs1057519955, COSV55299045; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779458, CM1412574, COSV58581974; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL4A4 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 24/36 reads (67%) | catalogued as rs534522842, COSV100306586, COSV61629550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DLL4 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 21/21 reads (100%) | catalogued as rs61750844, CM159185, COSV51060953; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.11907G>A p.W3969* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as rs1561122898, COSV54204150; ClinVar: pathogenic; called by muse, varscan2
- DOCK7 | c.3976C>T p.R1326* (on ENST00000635253 / NM_001367561.1; = p.R1295* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 77/162 reads (48%) | catalogued as rs756535975, COSV52000387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5434G>A p.E1812K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377267777, CM114226; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NPHP1 | c.1036C>T p.R346* (on ENST00000393272 / NM_207181.4; = p.R347* on NM_000272.5) | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as rs765263671, CM080456, COSV57206565; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.530A>T p.Y177F | Missense Mutation (SNP) | VAF 42/48 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as CD983505, COSV64289389, COSV64289854, COSV64294530, COSV64297160; called by muse, mutect2, varscan2
- STK19 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 44/96 reads (46%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs267600971, COSV61712753; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 55/56 reads (98%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.560-2A>C p.X187_splice | Splice Site (SNP) | VAF 18/52 reads (35%) | hotspot (GDC flag); catalogued as CS150685, CS941545, COSV52664494, COSV52666095, COSV52685228; called by muse, varscan2
- TP63 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 53/184 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs142762485, COSV53196450; called by muse, mutect2, varscan2
- A1CF | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 14/17 reads (82%) | catalogued as rs772118222, COSV50957228; called by muse, mutect2, varscan2
- A2M | c.1055T>C p.F352S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59382927; called by muse, mutect2, varscan2
- A2ML1 | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV55285714; called by muse, mutect2, varscan2
- A4GALT | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV50743979; called by muse, mutect2, varscan2
- AADACL2 | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 150/156 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62929532; called by muse, mutect2, varscan2
- ABCA1 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1461590067, COSV66063776; called by muse, mutect2, varscan2
- ABCA10 | c.1106A>C p.N369T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV52218302; called by muse, mutect2, varscan2
- ABCA12 | c.1374G>A p.M458I (on ENST00000272895 / NM_173076.3; = p.M140I on NM_015657.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1265368298, COSV55949349; called by muse, mutect2, varscan2
- ABCA13 | c.13267C>T p.P4423S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs763329595, COSV68943355; called by muse, mutect2, varscan2
- ABCA13 | c.13816G>A p.D4606N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV68943356; called by muse, mutect2, varscan2
- ABCA2 | c.2983C>T p.Q995* (on ENST00000614293; = p.Q965* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/70 reads (63%) | catalogued as COSV55797478; called by muse, mutect2, varscan2
- ABCA6 | c.2392T>G p.F798V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as COSV52635648; called by muse, mutect2, varscan2
- ABCA7 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs766893839, COSV54024083; called by muse, mutect2, varscan2
- ABCA7 | c.4616C>T p.S1539F | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54024099; called by muse, mutect2, varscan2
- ABCA9 | c.274A>C p.N92H | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV60620615; called by muse, mutect2
- ABCB10 | c.2060T>G p.V687G | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV60619794; called by muse, mutect2, varscan2
- ABCC10 | c.2903T>G p.L968R (on ENST00000372530 / NM_001198934.2; = p.L940R on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55084347; called by muse, mutect2, varscan2
- ABCC12 | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369032761, COSV60911577; called by muse, mutect2, varscan2
- ABCC2 | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 41/45 reads (91%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs773188597, COSV64984576; called by muse, mutect2, varscan2
- ABCC5 | c.3736T>G p.L1246V | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.217); catalogued as COSV55587140; called by muse, mutect2, varscan2
- ABCC6 | c.3163G>A p.V1055I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV52741257; called by muse, mutect2, varscan2
- ABCC9 | c.3802A>G p.N1268D | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV53962674; called by muse, mutect2, varscan2
- ABCC9 | c.401T>A p.L134H | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs764416164, COSV53962703, COSV53964608; called by muse, mutect2, varscan2
- ABCG1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100643388, COSV59200643; called by muse, mutect2, varscan2
- ABCG8 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.028); catalogued as rs762135880, COSV55390723; called by muse, mutect2, varscan2
- ABHD16A | c.1166A>C p.K389T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65451337; called by muse, mutect2, varscan2
- ABI1 | c.547A>G p.S183G | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV61015036; called by muse, mutect2, varscan2
- ABI3BP | c.332A>C p.K111T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52528342; called by muse, mutect2, varscan2
- ABITRAM | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59828884; called by muse, mutect2, varscan2
- ABRA | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as rs780637593, COSV61731924; called by muse, varscan2
- AC002094.3 | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.001); catalogued as COSV52645922; called by muse, mutect2, varscan2
- AC100868.1 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1257628043, COSV51837967; called by muse, mutect2, varscan2
- AC136428.1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 122/132 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV101434962; called by muse, mutect2, varscan2
- ACAN | c.4303G>A p.G1435R | Missense Mutation (SNP) | VAF 112/208 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1008142921, COSV61355884; called by muse, varscan2
- ACAN | c.4724G>A p.G1575D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.174); catalogued as rs752861429, COSV61355896; called by muse, mutect2, varscan2
- ACBD3 | c.702A>C p.E234D | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.899); catalogued as COSV64729646; called by muse, mutect2, varscan2
- ACBD5 | c.1352T>C p.L451P (on ENST00000375888 / NM_001352568.1; = p.L442P on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV65518008; called by muse, mutect2
- ACCSL | c.1166T>C p.V389A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1388299618, COSV66580011; called by muse, mutect2, varscan2
- ACD | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as COSV54665920, COSV99538042; called by muse, mutect2, varscan2
- ACKR1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 258/502 reads (51%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as COSV63671687; called by muse, mutect2, varscan2
- ACLY | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61249256; called by muse, mutect2, varscan2
- ACMSD | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598886, COSV51605536, COSV51606634; called by muse, mutect2, varscan2
- ACOT11 | c.1130T>A p.V377D | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as COSV59346181; called by muse, mutect2, varscan2
- ACOXL | c.1390G>A p.D464N (on ENST00000389811 / NM_001371254.1; = p.D434N on NM_001142807.4) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV67733709; called by muse, mutect2, varscan2
- ACSF2 | c.126C>T p.L42= | Splice Region (SNP) | VAF 10/12 reads (83%) | catalogued as COSV55949766; called by muse, mutect2, varscan2
- ACSF2 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs578192196, COSV51971258; called by muse, mutect2, varscan2
- ACSL1 | c.576A>T p.K192N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV55660633; called by muse, mutect2, varscan2
- ACSM2A | c.1151G>A p.G384E (on ENST00000219054; = p.G305E on NM_001308169.2) | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1410075998, COSV99525061; called by muse, varscan2
- ACSM2A | c.1222G>A p.G408R (on ENST00000219054; = p.G329R on NM_001308169.2) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54582225; called by muse, mutect2, varscan2
- ACSM2B | c.1624A>G p.R542G | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61656693; called by muse, mutect2, varscan2
- ACSM2B | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV61656697; called by muse, mutect2, varscan2
- ACTR1B | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376259596; called by muse, mutect2, varscan2
- ACTRT1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 43/44 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64418933; called by muse, mutect2, varscan2
- ADAD1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV56641542; called by muse, mutect2, varscan2
- ADAM12 | c.2390A>C p.N797T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.101); catalogued as COSV64124319; called by muse, mutect2, varscan2
- ADAM18 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); catalogued as rs767774627, COSV55843788, COSV55855271; called by muse, varscan2
- ADAM18 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV55843802; called by muse, mutect2, varscan2
- ADAM2 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.261); catalogued as rs529358916, COSV55858850; called by muse, mutect2, varscan2
- ADAM21 | c.164C>G p.A55G | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV50788685, COSV99960720; called by muse, mutect2, varscan2
- ADAM22 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55969702; called by muse, mutect2, varscan2
- ADAM32 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as COSV65947132; called by muse, mutect2, varscan2
- ADAMTS1 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213527598, COSV53168697; called by muse, mutect2, varscan2
- ADAMTS12 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 82/103 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100711384, COSV61255573; called by muse, mutect2, varscan2
- ADAMTS15 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54502915; called by muse, mutect2, varscan2
- ADAMTS18 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 32/38 reads (84%) | catalogued as rs747773771, COSV51398816; called by muse, mutect2, varscan2
- ADAMTS18 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51398827; called by muse, mutect2, varscan2
- ADAMTS3 | c.204G>C p.R68S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV54384788; called by muse, mutect2, varscan2
- ADAMTS6 | c.2093G>A p.G698E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV66856785; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1313A>G p.Q438R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.081); catalogued as COSV54996464; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57860081; called by muse, mutect2, varscan2
- ADAMTSL5 | c.247T>G p.L83V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.39); catalogued as rs757052752, COSV100389093; called by muse, mutect2, varscan2
- ADCY4 | c.1909-1G>A p.X637_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | catalogued as COSV60251967; called by muse, mutect2, varscan2
- ADCY5 | c.3578A>G p.K1193R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV59194157; called by muse, mutect2, varscan2
- ADCY5 | c.3049C>T p.L1017F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59194168; called by muse, mutect2, varscan2
- ADCY6 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 116/155 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV57166246; called by muse, mutect2, varscan2
- ADCY8 | c.2747G>A p.G916E | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV53896502; called by muse, mutect2, varscan2
- ADCY9 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs779084996, COSV53571472; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.425); catalogued as COSV58441316; called by muse, mutect2, varscan2
- ADGRE2 | c.1983T>G p.I661M | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV59691723; called by muse, mutect2, varscan2
- ADGRF1 | c.2681C>T p.T894I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV51943953; called by muse, mutect2, varscan2
- ADGRF5 | c.3368G>A p.S1123N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51929786; called by muse, mutect2, varscan2
- ADGRF5 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.576); catalogued as COSV51929830; called by muse, mutect2, varscan2
- ADGRG2 | c.1291G>A p.G431S (on ENST00000379869 / NM_001079858.3; = p.G428S on NM_005756.4) | Missense Mutation (SNP) | VAF 43/43 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV61337520; called by muse, mutect2, varscan2
- ADGRG4 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs778066740, COSV54949463; called by muse, mutect2, varscan2
- ADGRL4 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.062); catalogued as rs1267251792, COSV66059241; called by muse, mutect2, varscan2
- ADGRV1 | c.2854C>T p.Q952* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs1441316383, COSV67978517; called by muse, mutect2, varscan2
- ADGRV1 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.374); catalogued as COSV67978235; called by muse, mutect2, varscan2
- ADGRV1 | c.5493G>A p.M1831I | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV67978523; called by muse, mutect2, varscan2
- ADGRV1 | c.11587C>T p.L3863F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV67978528; called by muse, mutect2, varscan2
- ADH1A | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV52924289; called by muse, mutect2, varscan2
- ADTRP | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57641744; called by muse, varscan2
- AFF2 | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 85/91 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53976811, COSV53998313; called by muse, mutect2, varscan2
- AGMO | c.1216T>G p.F406V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV61105740; called by muse, mutect2, varscan2
- AGMO | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs1273447604, COSV61105744; called by muse, mutect2
- AGO4 | c.152T>G p.I51S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV64616411; called by muse, mutect2, varscan2
- AGR3 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1349814444, COSV60037148; called by muse, mutect2, varscan2
- AGR3 | c.34T>G p.L12V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV60037156; called by muse, mutect2, varscan2
- AGT | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs781549278, COSV64183713; called by muse, mutect2, varscan2
- AGXT2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761319044, COSV51483937; called by muse, varscan2
- AGXT2 | c.553T>G p.S185A | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV51483951; called by muse, mutect2
- AHNAK | c.3672G>A p.M1224I | Missense Mutation (SNP) | VAF 117/513 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs753704810, COSV57203658; called by muse, mutect2, varscan2
- AHSG | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 126/182 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99889929; called by muse, mutect2, varscan2
- AHSG | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 125/179 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99889933; called by muse, mutect2, varscan2
- AK9 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53419678; called by muse, mutect2, varscan2
- AKAP1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs895728229, COSV58468748; called by muse, mutect2, varscan2
- AKAP4 | c.2140T>C p.Y714H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV62073679; called by muse, mutect2, varscan2
- AKAP6 | c.3304T>G p.F1102V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs779600778, COSV55205049; called by muse, mutect2, varscan2
- AKAP6 | c.4721G>A p.G1574E | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs765589655, COSV55205061; called by muse, mutect2, varscan2
- AKR1A1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768922532, COSV61086243; called by muse, mutect2, varscan2
- AKR1B15 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs773347979, COSV71151011; called by muse, varscan2
- AKR1C4 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as rs1394006882, COSV54122301; called by muse, varscan2
- AL121899.2 | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 53/130 reads (41%) | catalogued as rs867276818, COSV67349713; called by muse, mutect2, varscan2
- AL645922.1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54959260, COSV54962083; called by muse, mutect2, varscan2
- ALG11 | c.1470A>T p.L490F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV101584264; called by muse, mutect2, varscan2
- ALG1L | c.268T>G p.F90V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61075254; called by muse, mutect2, varscan2
- ALK | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66557447; called by muse, mutect2, varscan2
- ALK | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs768680011, COSV66557450; called by muse, mutect2, varscan2
- ALOX12B | c.1228T>C p.C410R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV59871016; called by muse, mutect2, varscan2
- ALPK1 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 38/61 reads (62%) | catalogued as rs1388112183, COSV51581917; called by muse, mutect2, varscan2
- ALPK2 | c.5797G>A p.A1933T | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64490280; called by muse, mutect2, varscan2
- ALPK2 | c.3687T>G p.N1229K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV64490282; called by muse, mutect2, varscan2
- ALPK2 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 84/92 reads (91%) | SIFT tolerated (0.84); PolyPhen benign (0.037); catalogued as COSV64490284; called by muse, mutect2, varscan2
- ALPK3 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.406); catalogued as COSV51929348; called by muse, mutect2, varscan2
- ALPK3 | c.4280A>C p.K1427T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV51929365; called by muse, mutect2, varscan2
- ALPL | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66375944; called by muse, mutect2, varscan2
- ALX3 | c.728A>G p.Q243R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV63928562; called by muse, mutect2, varscan2
- AMBP | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs753980856, COSV99468921; called by muse, mutect2, varscan2
- AMER1 | c.3353C>T p.A1118V | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV57654900; called by muse, mutect2, varscan2
- AMIGO1 | c.695T>A p.L232Q | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63990232; called by muse, mutect2, varscan2
- AMOTL1 | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV58565036; called by muse, mutect2, varscan2
- ANGEL1 | c.894A>C p.E298D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99200356; called by muse, mutect2, varscan2
- ANGPT1 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV52430924; called by muse, mutect2, varscan2
- ANGPT1 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781505587; called by muse, mutect2, varscan2
- ANGPT4 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV67920616; called by muse, mutect2, varscan2
- ANGPTL4 | c.621G>C p.Q207H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as COSV56844293; called by muse, mutect2, varscan2
- ANGPTL5 | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV57531827; called by muse, mutect2, varscan2
- ANK1 | c.3146A>C p.K1049T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV55872852; called by muse, mutect2
- ANK2 | c.7388C>T p.S2463F | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52146222; called by muse, mutect2, varscan2
- ANK2 | c.11338G>A p.E3780K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV52146231; called by muse, mutect2, varscan2
- ANK3 | c.10576G>A p.E3526K | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.081); catalogued as COSV55044324; called by muse, mutect2, varscan2
- ANK3 | c.7466G>A p.G2489E | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.506); catalogued as rs1178363583, COSV55044332; called by muse, mutect2, varscan2
- ANK3 | c.7037T>A p.I2346N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55044341; called by muse, mutect2, varscan2
- ANK3 | c.6071C>T p.S2024F | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV55060523; called by muse, mutect2, varscan2
- ANK3 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1459024330, COSV55044360; called by muse, mutect2, varscan2
- ANK3 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55044377; called by muse, mutect2, varscan2
- ANKAR | c.4159A>C p.K1387Q | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV51461743; called by muse, mutect2, varscan2
- ANKRD12 | c.1838A>T p.H613L | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV100040991; called by muse, mutect2, varscan2
- ANKRD13C | c.587T>G p.L196R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52029082; called by muse, mutect2
- ANKRD30A | c.1076G>A p.R359K (on ENST00000611781; = p.R303K on NM_052997.2) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs756620752, COSV64603909; called by muse, mutect2, varscan2
- ANKRD30A | c.3124G>A p.D1042N (on ENST00000611781; = p.D986N on NM_052997.2) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs772800090, COSV64603921, COSV64622668; called by muse, mutect2, varscan2
- ANKRD34B | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs865774055, COSV58613353; called by muse, mutect2, varscan2
- ANKS1B | c.1921T>G p.L641V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.173); catalogued as COSV61335168; called by muse, mutect2, varscan2
- ANKS3 | c.1181A>G p.K394R | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.985); catalogued as COSV58507206; called by muse, mutect2
- ANO1 | c.2090A>G p.Q697R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100303828; called by muse, mutect2, varscan2
- ANO3 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.107); catalogued as rs1328657467, COSV56780738; called by muse, varscan2
- ANO7 | c.505T>C p.Y169H (on ENST00000274979; = p.Y115H on NM_001370694.2) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV51468148; called by muse, mutect2, varscan2
- ANO8 | c.1222A>T p.S408C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50173093; called by muse, mutect2, varscan2
- ANO9 | c.1496T>C p.V499A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV60382395; called by muse, mutect2, varscan2
- ANPEP | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55589207; called by muse, mutect2, varscan2
- ANXA1 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV57410389; called by muse, mutect2, varscan2
- ANXA9 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV64484149; called by muse, mutect2, varscan2
- AOAH | c.1315A>C p.N439H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.191); catalogued as COSV51735728; called by muse, mutect2, varscan2
- AOC2 | c.2198A>C p.N733T (on ENST00000253799 / NM_009590.4; = p.N706T on NM_001158.5) | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53824204; called by muse, varscan2
- AOC3 | c.1501T>G p.F501V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV53824212; called by muse, mutect2, varscan2
- AOX1 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV65980051; called by muse, mutect2
- AOX1 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV65980055; called by muse, mutect2, varscan2
- AOX1 | c.3862A>T p.S1288C | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV53495359, COSV53495896; called by muse, mutect2
- AP002512.3 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.897); catalogued as rs550414369, COSV54405546; called by muse, mutect2, varscan2
- AP002748.5 | c.1160T>A p.L387Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59146906; called by muse, mutect2, varscan2
- AP002748.5 | c.1784A>C p.K595T | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.866); catalogued as COSV59146927; called by muse, mutect2, varscan2
- AP3M2 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142101815, COSV51527608; called by muse, mutect2, varscan2
- AP4B1 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200276550, COSV56723272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBB1 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs371560245; called by muse, mutect2, varscan2
- APBB1IP | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100881997; called by muse, mutect2, varscan2
- APBB2 | c.956G>A p.R319Q (on ENST00000295974 / NM_001166050.2; = p.R320Q on NM_004307.2) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.477); catalogued as rs750071396, COSV55947103, COSV55956888; called by muse, mutect2, varscan2
- APC | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as CD106445, CM010755, COSV57324987, COSV57362864; called by muse, mutect2, varscan2
- APC2 | c.2537A>C p.K846T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV52016081; called by mutect2, varscan2
- APC2 | c.5279A>C p.K1760T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV52016090; called by muse, mutect2, varscan2
- APCDD1L | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64485347; called by muse, mutect2, varscan2
- APEH | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56532070; called by muse, mutect2, varscan2
- APLP1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV55701686; called by muse, mutect2, varscan2
- APOA5 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as COSV57062215; called by muse, mutect2, varscan2
- APOBEC2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.027); catalogued as COSV55141977; called by muse, mutect2
- APOC3 | c.213A>C p.K71N | Missense Mutation (SNP) | VAF 60/65 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV52635278; called by muse, mutect2, varscan2
- APOH | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.392); catalogued as COSV52771376; called by muse, mutect2, varscan2
- APOL1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV59868453; called by muse, mutect2, varscan2
- APOL3 | c.646A>G p.S216G (on ENST00000349314 / NM_145640.2; = p.S145G on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62579188; called by muse, mutect2, varscan2
- APOL5 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 125/225 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.21); catalogued as rs1485297376, COSV50766366; called by muse, mutect2, varscan2
- APPL2 | c.122T>G p.L41R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.741); catalogued as COSV51588155; called by muse, mutect2, varscan2
- AQP1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs748039521, COSV61266109; called by muse, mutect2, varscan2
- AQP10 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV61476274; called by muse, mutect2, varscan2
- ARAP1 | c.2308A>C p.S770R (on ENST00000393609 / NM_001040118.2; = p.S525R on NM_015242.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV61989335; called by muse, mutect2
- ARAP3 | c.4102C>T p.Q1368* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV53348628; called by muse, mutect2, varscan2
- ARAP3 | c.2659G>A p.G887S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.152); catalogued as rs1024038896, COSV53348639; called by mutect2, varscan2
- AREL1 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.852); catalogued as COSV62665452; called by muse, mutect2
- ARFGEF2 | c.2381A>C p.K794T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64210467; called by muse, mutect2, varscan2
- ARFGEF2 | c.3397C>T p.R1133* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | catalogued as COSV64210470; called by muse, mutect2, varscan2
- ARFGEF3 | c.4329T>G p.D1443E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV52450208; called by muse, mutect2, varscan2
- ARFIP2 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54446178; called by muse, mutect2, varscan2
- ARHGAP1 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61734317; called by muse, mutect2, varscan2
- ARHGAP17 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV51504866; called by muse, mutect2, varscan2
- ARHGAP18 | c.503T>G p.I168S | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV63763363; called by muse, mutect2, varscan2
- ARHGAP24 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 21/33 reads (64%) | catalogued as rs749366950, COSV67836561; called by muse, mutect2, varscan2
- ARHGAP25 | c.1106A>C p.N369T (on ENST00000409202 / NM_001007231.3; = p.N361T on NM_014882.3) | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs1236946166, COSV54898374; called by muse, mutect2, varscan2
- ARHGAP29 | c.2417T>G p.L806R | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53108178; called by muse, mutect2
- ARHGAP32 | c.2450C>T p.S817F (on ENST00000310343 / NM_001378025.1; = p.S468F on NM_014715.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV59843278; called by muse, mutect2, varscan2
- ARHGAP36 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1460939004, COSV52263824; called by muse, mutect2, varscan2
- ARHGAP39 | c.2978C>T p.P993L (on ENST00000276826 / NM_001308208.2; = p.P1024L on NM_025251.2) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV99430634; called by muse, mutect2, varscan2
- ARHGAP45 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs765007544, COSV57429264; called by muse, mutect2, varscan2
- ARHGDIB | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56762315; called by muse, mutect2, varscan2
- ARHGEF10 | c.2422T>A p.C808S (on ENST00000398564; = p.C783S on NM_014629.4) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV50642574; called by muse, mutect2, varscan2
- ARHGEF15 | c.2087A>G p.Q696R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV62724332; called by muse, varscan2
- ARHGEF15 | c.2108G>A p.G703E | Missense Mutation (SNP) | VAF 101/106 reads (95%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV62724337; called by muse, varscan2
- ARHGEF16 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772762781, COSV65682450; called by muse, varscan2
- ARHGEF17 | c.5783T>C p.L1928P | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55229386; called by muse, mutect2
- ARHGEF26 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62843841; called by muse, mutect2, varscan2
- ARHGEF38 | c.644T>A p.I215N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV54440763; called by muse, mutect2, varscan2
- ARID2 | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 41/219 reads (19%) | catalogued as COSV57595998; called by muse, mutect2, varscan2
- ARID3B | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 114/129 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60556394; called by muse, mutect2, varscan2
- ARMC12 | c.841G>A p.E281K (on ENST00000373866 / NM_001286574.2; = p.E308K on NM_145028.5) | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.767); catalogued as COSV55359162; called by muse, mutect2, varscan2
- ARMC4 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV53462652, COSV99518710; called by muse, mutect2, varscan2
- ARMC4 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.384); catalogued as rs867318336, COSV53462676; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.413A>C p.D138A | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV63437085; called by muse, mutect2, varscan2
- ARMH4 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs774058781, COSV50761621; called by muse, mutect2, varscan2
- ARNT | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV62229663; called by muse, mutect2, varscan2
- ARPC4 | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV55027981; called by muse, mutect2, varscan2
- ARSB | c.1434T>G p.D478E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV53719032; called by muse, mutect2, varscan2
- ART5 | c.700A>T p.R234* | Nonsense Mutation (SNP) | VAF 26/140 reads (19%) | catalogued as COSV63364054; called by muse, mutect2, varscan2
- ASAP3 | c.2540G>A p.R847K | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV60873029; called by muse, mutect2, varscan2
- ASAP3 | c.1495A>C p.N499H | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60873038; called by muse, mutect2
- ASB10 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.028); catalogued as COSV51994180; called by muse, mutect2, varscan2
- ASB12 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1298297861, COSV62856043; called by muse, mutect2, varscan2
- ASB15 | c.311G>A p.W104* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV51923687; called by muse, varscan2
- ASB15 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV51923704; called by muse, varscan2
- ASB2 | c.1388G>A p.G463D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60110376; called by muse, mutect2, varscan2
- ASH1L | c.3080C>T p.A1027V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64205466; called by muse, mutect2, varscan2
- ASIC4 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs777137660, COSV61730953; called by muse, varscan2
- ASMT | c.899C>T p.S300F (on ENST00000381229; = p.S328F on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67109561; called by muse, mutect2, varscan2
- ASPH | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.253); catalogued as COSV62857934; called by muse, mutect2
- ASPHD2 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1459195136, COSV53218007; called by muse, mutect2, varscan2
- ASPM | c.6310T>C p.Y2104H | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54124681; called by muse, mutect2, varscan2
- ASPM | c.5842C>T p.R1948C | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as rs375852743; called by muse, mutect2, varscan2
- ASTL | c.850A>C p.S284R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV60903561; called by muse, mutect2, varscan2
- ASTN1 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 134/275 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV56061529, COSV56073522; called by muse, mutect2, varscan2
- ASTN2 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 76/119 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV57751179; called by muse, mutect2, varscan2
- ASXL3 | c.1058T>G p.F353C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52456793, COSV52457412; called by muse, mutect2
- ASXL3 | c.3523C>T p.L1175F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.28); catalogued as COSV52457472; called by muse, mutect2, varscan2
- ASZ1 | c.690C>T p.I230= | Splice Region (SNP) | VAF 5/17 reads (29%) | catalogued as rs1156593975, COSV52911184; called by muse, mutect2, varscan2
- ATF7-NPFF | c.1370A>G p.Y457C | Missense Mutation (SNP) | VAF 37/106 reads (35%) | PolyPhen possibly damaging (0.883); catalogued as COSV57198975; called by muse, mutect2, varscan2
- ATG4C | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV58603724; called by muse, mutect2, varscan2
- ATL1 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63295900; called by muse, mutect2, varscan2
- ATP13A3 | c.2011T>C p.F671L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV55461469; called by muse, mutect2, varscan2
- ATP1A3 | c.332C>T p.A111V (on ENST00000545399 / NM_001256214.2; = p.A98V on NM_152296.5) | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as COSV57485086; called by muse, mutect2, varscan2
- ATP2A1 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV100837210; called by muse, varscan2
- ATP2A1 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100837211; called by muse, varscan2
- ATP2A2 | c.2057T>G p.I686S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875037; called by muse, mutect2, varscan2
- ATP2B1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV53803872; called by muse, mutect2, varscan2
- ATP6V0A1 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as COSV52870707; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2165A>C p.H722P | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59472572; called by muse, mutect2, varscan2
- ATP6V1G3 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV55278229; called by muse, varscan2
- ATP7B | c.1288A>C p.S430R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV54435180; called by muse, mutect2
- ATP8A1 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV52528754; called by muse, mutect2, varscan2
- ATP8B1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 88/101 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs1455274169, COSV52173035; called by muse, mutect2, varscan2
- ATP8B3 | c.1721T>C p.V574A | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59540023; called by muse, mutect2
- ATP9A | c.893T>G p.L298W | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as rs752039313, COSV100124581; called by mutect2, varscan2
- ATP9A | c.892T>G p.L298V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV100124584; called by muse, mutect2, varscan2
- ATPAF1 | c.272A>G p.D91G (on ENST00000574428; = p.D114G on NM_022745.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as COSV61304397; called by muse, mutect2
- ATXN1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs761009054, COSV55208412; called by muse, mutect2, varscan2
- ATXN10 | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53293584; called by muse, mutect2, varscan2
- AUNIP | c.1068A>C p.Q356H | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV65352422; called by muse, mutect2, varscan2
- AURKC | c.563C>T p.S188F (on ENST00000302804 / NM_001015878.2; = p.S154F on NM_003160.3) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766389749, COSV100248844, COSV57136931; called by muse, mutect2, varscan2
- AXDND1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV62639687; called by muse, varscan2
- AXL | c.1396A>C p.I466L (on ENST00000301178 / NM_021913.5; = p.I457L on NM_001699.6) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV56563728; called by muse, mutect2, varscan2
- B3GALT1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.301); catalogued as rs755628484, COSV59908038; called by muse, mutect2, varscan2
- B3GNT4 | c.5T>G p.L2R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs762542367, COSV57335718; called by muse, mutect2
- B3GNT7 | c.386A>C p.K129T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55005781; called by muse, mutect2, varscan2
- B3GNT7 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.202); catalogued as COSV55005790; called by muse, mutect2, varscan2
- B4GALNT2 | c.796A>C p.K266Q | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV55924683; called by muse, mutect2, varscan2
- B4GALNT2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 138/147 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs758644590, COSV55924690, COSV55928638; called by muse, mutect2, varscan2
- BACE1 | c.1140T>G p.C380W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56117634; called by muse, varscan2
- BAK1 | c.256A>G p.N86D | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs1283682592, COSV62349308; called by muse, mutect2, varscan2
- BARHL2 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV64980760; called by muse, mutect2, varscan2
- BAZ1A | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.585); catalogued as COSV62409004; called by muse, mutect2, varscan2
- BAZ1B | c.2778A>C p.K926N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100289650; called by muse, mutect2, varscan2
- BBOF1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67454446; called by muse, mutect2
- BBS2 | c.1649T>A p.L550H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55325101; called by muse, mutect2, varscan2
- BBS2 | c.1408C>T p.H470Y | Missense Mutation (SNP) | VAF 51/54 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV55325108, COSV55328213; called by muse, mutect2, varscan2
- BBS7 | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV52654270; called by muse, mutect2, varscan2
- BCAN | c.816A>C p.E272D | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.649); catalogued as COSV61255500; called by muse, mutect2, varscan2
- BCAN | c.1772C>A p.A591D | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100227966; called by muse, mutect2, varscan2
- BCAS1 | c.1633A>G p.R545G | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV65083824; called by muse, mutect2, varscan2
- BCAS1 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); catalogued as COSV65083831; called by muse, varscan2
- BCAT1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV53907451; called by muse, mutect2, varscan2
- BCL11B | c.2513A>C p.K838T (on ENST00000357195 / NM_001282237.2; = p.K767T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61733260; called by muse, mutect2, varscan2
- BCL6 | c.1942C>T p.H648Y | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99215509; called by muse, mutect2, varscan2
- BCL9L | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 70/75 reads (93%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV52681922; called by muse, mutect2, varscan2
- BCLAF1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV62140394; called by muse, mutect2, varscan2
- BCLAF3 | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1268670979, COSV61413069; called by muse, mutect2, varscan2
- BCR | c.830A>G p.Q277R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59926471; called by muse, mutect2
- BEND4 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs941087225, COSV72468928, COSV72469488; called by muse, mutect2, varscan2
- BEND7 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs780291533, COSV61987320; called by muse, mutect2, varscan2
- BFSP2 | c.661A>G p.M221V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV56586303; called by muse, mutect2, varscan2
- BICD1 | c.428A>C p.N143T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV55674771; called by muse, mutect2
- BICRA | c.1493T>C p.L498P | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1306813061, COSV67603714; called by muse, mutect2, varscan2
- BIRC6 | c.7886T>G p.L2629R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.602); catalogued as COSV70195550; called by muse, mutect2, varscan2
- BIRC6 | c.12556C>T p.R4186* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV70195557; called by muse, mutect2, varscan2
- BMP10 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.164); catalogued as COSV54894037; called by muse, mutect2, varscan2
- BMP7 | c.473T>G p.F158C | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67779553; called by muse, mutect2, varscan2
- BMPR2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV65807554; called by muse, mutect2, varscan2
- BNC2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV101032591; called by muse, mutect2
- BNC2 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.02); catalogued as COSV101032592; called by muse, mutect2, varscan2
- BNIP1 | c.225A>C p.Q75H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.473); catalogued as COSV51569950; called by muse, mutect2, varscan2
- BNIP1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs775764491, COSV51569959; called by muse, mutect2, varscan2
- BNIP5 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV71325282, COSV71325450; called by muse, mutect2, varscan2
- BNIP5 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV71325262; called by muse, mutect2, varscan2
- BPI | c.290C>T p.S97F (on ENST00000262865; = p.S93F on NM_001725.3) | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as COSV53403909; called by muse, mutect2, varscan2
- BPI | c.722T>G p.V241G (on ENST00000262865; = p.V237G on NM_001725.3) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV53403917; called by muse, mutect2, varscan2
- BRAF | c.1574T>A p.L525* (on ENST00000288602 / NM_001374244.1; = p.L485* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 33/60 reads (55%) | catalogued as CM086782, COSV56173975, COSV56190001, COSV99956290; called by muse, mutect2, varscan2
- BRCA1 | c.3896A>T p.Q1299L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV58784081; called by muse, mutect2
- BRCA1 | c.805T>G p.L269V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.521); catalogued as COSV58784091; called by muse, mutect2, varscan2
- BRD4 | c.3682C>T p.R1228C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54582278; called by muse, mutect2, varscan2
- BRD4 | c.2022T>G p.C674W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54582287; called by muse, mutect2, varscan2
- BRD9 | c.1541A>G p.E514G | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.606); catalogued as COSV60244620; called by muse, mutect2, varscan2
- BRDT | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.247); catalogued as COSV62863294; called by muse, mutect2, varscan2
- BRICD5 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV57026475; called by muse, mutect2, varscan2
- BRINP3 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 122/246 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV66513604, COSV66513646; called by muse, varscan2
- BRINP3 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs867625077, COSV66513616; called by muse, mutect2, varscan2
- BRPF3 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768982236, COSV60205910; called by muse, mutect2, varscan2
- BRWD1 | c.2086A>C p.S696R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV60892715; called by muse, mutect2, varscan2
- BSN | c.633G>A p.Q211= | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99607781; called by muse, mutect2, varscan2
- BSN | c.633+1G>A p.X211_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99607785; called by muse, mutect2, varscan2
- BSN | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs977844076, COSV56513022; called by muse, mutect2, varscan2
- BSN | c.2355A>C p.E785D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56513032; called by muse, mutect2, varscan2
- BSN | c.8976A>C p.K2992N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56513047; called by muse, mutect2, varscan2
- BTBD11 | c.2140C>T p.P714S (on ENST00000280758 / NM_001018072.2; = p.P251S on NM_001017523.2) | Missense Mutation (SNP) | VAF 60/68 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55017092; called by muse, mutect2, varscan2
- BTBD8 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61544966, COSV61546758; called by muse, mutect2, varscan2
- BTBD8 | c.1022G>A p.W341* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV61544975; called by muse, mutect2, varscan2
- BTG4 | c.629A>C p.K210T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as COSV63635219; called by muse, mutect2, varscan2
- BTNL3 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs996332310, COSV61564340; called by muse, mutect2, varscan2
- BTNL8 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV51456815; called by muse, mutect2, varscan2
- BUB1B | c.2734T>C p.F912L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55009891; called by muse, mutect2, varscan2
- BUB3 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs868083882, COSV64363518; called by muse, mutect2, varscan2
- BZW2 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV51753782; called by muse, mutect2, varscan2
- C10orf71 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs762918373, COSV60504482; called by muse, varscan2
- C11orf94 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53796665; called by muse, mutect2, varscan2
- C16orf46 | c.126T>G p.Y42* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV55150146; called by muse, mutect2, varscan2
- C17orf100 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 45/47 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV56725701; called by muse, mutect2, varscan2
- C17orf80 | c.930A>C p.K310N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV52144898; called by muse, mutect2, varscan2
- C18orf32 | c.195A>C p.K65N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.165); catalogued as COSV100271554; called by muse, mutect2, varscan2
- C1GALT1C1 | c.469T>G p.F157V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as COSV58973740; called by muse, mutect2
- C1QTNF3 | c.299A>C p.Q100P | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV51467676; called by muse, mutect2, varscan2
- C1QTNF8 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.194); catalogued as COSV60518652; called by muse, mutect2, varscan2
- C1QTNF9 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV100129773; called by muse, mutect2, varscan2
- C1R | c.352G>A p.E118K (on ENST00000536053 / NM_001354346.2; = p.E104K on NM_001733.7) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); catalogued as rs747201064, COSV56923459, COSV56926221; called by muse, mutect2, varscan2
- C1orf158 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.967); catalogued as COSV55346108, COSV99847200; called by muse, mutect2, varscan2
- C1orf158 | c.238A>C p.K80Q | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.477); catalogued as COSV55346120; called by muse, mutect2
- C1orf74 | c.256del p.E87Rfs*7 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as COSV99160475; called by mutect2, pindel, varscan2
- C1orf94 | c.1444C>T p.Q482* (on ENST00000488417 / NM_001134734.2; = p.Q292* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV64912975; called by muse, mutect2, varscan2
- C20orf194 | c.3042A>C p.K1014N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV52691422; called by muse, mutect2, varscan2
- C22orf42 | c.373-1G>A p.X125_splice | Splice Site (SNP) | VAF 26/78 reads (33%) | catalogued as COSV66075241; called by muse, mutect2, varscan2
- C2CD3 | c.4102T>C p.S1368P | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV58089567; called by muse, mutect2, varscan2
- C2orf16 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV68645361; called by muse, mutect2, varscan2
- C2orf16 | c.1390A>T p.T464S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV68645365; called by muse, mutect2, varscan2
- C2orf16 | c.5818G>A p.G1940R | Missense Mutation (SNP) | VAF 77/113 reads (68%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs951625629, COSV62673789; called by muse, mutect2, varscan2
- C2orf42 | c.1227A>C p.K409N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV52448885; called by muse, mutect2, varscan2
- C3orf20 | c.950A>C p.K317T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV53782492; called by muse, mutect2, varscan2
- C3orf20 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.52); catalogued as COSV53782507; called by muse, mutect2, varscan2
- C3orf38 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772721082, COSV59628306; called by muse, mutect2, varscan2
- C3orf56 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV67756003; called by muse, mutect2, varscan2
- C5AR2 | c.974A>C p.K325T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.106); catalogued as COSV57255469; called by muse, mutect2, varscan2
- C6 | c.2674G>A p.G892R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.319); catalogued as COSV54704935; called by muse, mutect2, varscan2
- C6 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 61/304 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV54704946; called by muse, mutect2, varscan2
- C6 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs774668030, COSV54704969; called by muse, mutect2, varscan2
- C6orf47 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs746312913, COSV63263589; called by muse, mutect2, varscan2
- CABIN1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs757455062, COSV54077607; called by muse, varscan2
- CABIN1 | c.640A>G p.R214G | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV54077619; called by muse, varscan2
- CABP4 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs11605013, COSV56885009; called by muse, mutect2, varscan2
- CABP5 | c.53A>C p.E18A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53151961; called by muse, mutect2, varscan2
- CACNA1B | c.974A>C p.D325A | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53113828; called by muse, mutect2, varscan2
- CACNA1B | c.6965C>T p.S2322L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs200832957, COSV53113896; called by muse, mutect2, varscan2
- CACNA1E | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 145/307 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as rs1219232478, COSV62382290, COSV62414513; called by muse, mutect2, varscan2
- CACNA1E | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100703800, COSV62382305; called by muse, mutect2, varscan2
- CACNA1E | c.2704G>A p.G902R | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV62382319; called by muse, mutect2, varscan2
- CACNA1E | c.4093C>T p.L1365F | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62382338, COSV62404344; called by muse, mutect2, varscan2
- CACNA1F | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782492780, COSV59902917; called by muse, mutect2, varscan2
- CACNA1F | c.3122+1G>A p.X1041_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | catalogued as COSV59903043; called by muse, mutect2, varscan2
- CACNA1H | c.5180A>C p.K1727T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV61983655; called by muse, mutect2, varscan2
- CACNA2D1 | c.2195G>A p.R732Q (on ENST00000356253 / NM_001366867.1; = p.R720Q on NM_000722.4) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as rs79127167, COSV62372664; called by muse, mutect2, varscan2
- CACNA2D2 | c.1776C>T p.I592= | Splice Region (SNP) | VAF 19/62 reads (31%) | catalogued as COSV56560483; called by muse, mutect2, varscan2
- CACNA2D2 | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56560490; called by muse, mutect2
- CACNA2D3 | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as COSV55513837; called by muse, varscan2
- CACNA2D3 | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55513847; called by muse, mutect2, varscan2
- CACNA2D3 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); catalogued as COSV55513854; called by muse, mutect2, varscan2
- CACNG3 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866765368, COSV50064089; called by muse, mutect2, varscan2
- CACNG4 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 76/79 reads (96%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as COSV50924139; called by muse, mutect2, varscan2
- CAD | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV53023615; called by muse, mutect2, varscan2
- CADPS | c.4026G>A p.M1342I | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV51867070; called by muse, mutect2, varscan2
- CADPS | c.3196G>T p.D1066Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51867111; called by muse, mutect2, varscan2
- CADPS2 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774058528, COSV57349553, COSV57376737; called by muse, mutect2, varscan2
- CAGE1 | c.2311G>A p.E771K (on ENST00000512086; = p.E635K on NM_205864.3) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); catalogued as COSV57074662; called by muse, mutect2, varscan2
- CAGE1 | c.1426G>A p.E476K (on ENST00000512086; = p.E340K on NM_205864.3) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs866412142, COSV57074675; called by muse, mutect2, varscan2
- CALCRL | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV66473476; called by muse, mutect2, varscan2
- CALN1 | c.212T>A p.M71K (on ENST00000329008 / NM_001017440.3; = p.M113K on NM_031468.4) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV61119994; called by muse, mutect2, varscan2
- CAMK4 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746112718, COSV56662242; called by muse, mutect2, varscan2
- CAMSAP2 | c.2469A>C p.K823N (on ENST00000236925 / NM_001297707.2; = p.K812N on NM_203459.3) | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV52666937; called by muse, varscan2
- CAMSAP3 | c.1333A>G p.T445A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV50330850; called by muse, mutect2, varscan2
- CANT1 | c.101C>G p.A34G | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100185209; called by muse, varscan2
- CAPN10 | c.1043A>C p.K348T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV99550068; called by muse, mutect2, varscan2
- CAPN7 | c.931A>C p.I311L | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV53776739; called by muse, mutect2, varscan2
- CAPZA1 | c.280A>C p.I94L | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV54144229; called by muse, mutect2, varscan2
- CARD6 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV54564208, COSV54564769; called by muse, mutect2, varscan2
- CASK | c.1350A>C p.E450D | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as COSV59361649; called by muse, mutect2, varscan2
- CASZ1 | c.3929C>T p.S1310F | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1325785507, COSV59732060; called by muse, mutect2, varscan2
- CATSPER4 | c.379A>C p.T127P | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV58792276; called by muse, mutect2, varscan2
- CATSPERB | c.2609G>A p.R870K | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760298597, COSV56422215; called by muse, mutect2, varscan2
- CATSPERB | c.2266C>T p.R756* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs146758171; called by muse, mutect2, varscan2
- CATSPERE | c.1077T>G p.I359M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV63675854; called by muse, mutect2, varscan2
- CAVIN2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 103/158 reads (65%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV58423225; called by muse, varscan2
- CAVIN2 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58423237; called by muse, mutect2, varscan2
- CBLIF | c.773A>C p.K258T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV57237960, COSV57238532; called by muse, mutect2, varscan2
- CBLL1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs764776585, COSV56028078; called by muse, mutect2, varscan2
- CBLN3 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52158730; called by muse, mutect2, varscan2
- CBX4 | c.1421A>G p.D474G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV53964378; called by muse, mutect2, varscan2
- CC2D1B | c.659A>C p.E220A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99429831; called by muse, mutect2, varscan2
- CC2D1B | c.174A>C p.E58D | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52558696; called by muse, mutect2, varscan2
- CCAR2 | c.1630T>C p.F544L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52383131; called by muse, mutect2, varscan2
- CCDC102B | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV60134557; called by muse, mutect2, varscan2
- CCDC141 | c.3722C>T p.S1241F | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV55368901; called by muse, mutect2, varscan2
- CCDC141 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 177/274 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs372879210; called by muse, mutect2, varscan2
- CCDC158 | c.3244G>A p.D1082N | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV66355187; called by muse, mutect2, varscan2
- CCDC158 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs370067451; called by muse, mutect2, varscan2
- CCDC173 | c.603A>C p.Q201H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV69572515; called by muse, mutect2, varscan2
- CCDC18 | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58141284; called by muse, mutect2, varscan2
- CCDC183 | c.1334A>T p.E445V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61033223; called by muse, mutect2, varscan2
- CCDC186 | c.2545T>C p.S849P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65160577; called by muse, mutect2, varscan2
- CCDC62 | c.2039C>T p.T680I | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs779952779, COSV99456777; called by muse, mutect2, varscan2
- CCDC74A | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as rs368704110; called by muse, mutect2, varscan2
- CCDC78 | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.323); catalogued as COSV53494823; called by muse, mutect2, varscan2
- CCDC83 | c.1229A>C p.K410T (on ENST00000342404 / NM_001286159.2; = p.K441T on NM_173556.5) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54699743; called by muse, mutect2, varscan2
- CCDC88C | c.4594T>G p.S1532A | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57795847; called by muse, mutect2, varscan2
- CCDC88C | c.1755G>A p.M585I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV66234066; called by muse, mutect2, varscan2
- CCDC96 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs1162691025, COSV100027857; called by muse, mutect2, varscan2
- CCIN | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV58724045; called by muse, mutect2, varscan2
- CCNA1 | c.700A>C p.K234Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV55219888, COSV55222941; called by muse, mutect2
- CCNB3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.043); catalogued as COSV52069946; called by muse, mutect2, varscan2
- CCNG1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1331708051, COSV61651843; called by muse, mutect2, varscan2
- CCNL1 | c.1302T>G p.S434R | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV55818433; called by muse, mutect2
- CCNT1 | c.1370A>G p.K457R | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1159987955, COSV56063216; called by muse, mutect2
- CCP110 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV66816512; called by muse, mutect2, varscan2
- CCR2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs934480642, COSV52747642; called by muse, mutect2, varscan2
- CCR4 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV58381407; called by muse, mutect2, varscan2
- CCSER1 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as COSV61407451; called by muse, mutect2, varscan2
- CCT8 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV54502892; called by muse, mutect2, varscan2
- CCT8L2 | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.107); catalogued as rs1221765417, COSV63461632; called by muse, mutect2, varscan2
- CD163 | c.3338C>T p.S1113F | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as COSV63129495; called by muse, mutect2, varscan2
- CD163 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs763870982, COSV63129524; called by muse, mutect2, varscan2
- CD163 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.935); catalogued as COSV63129531; called by muse, mutect2, varscan2
- CD163 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV63129543; called by muse, mutect2, varscan2
- CD1B | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 156/337 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1425963030, COSV63803782; called by muse, mutect2, varscan2
- CD200 | c.617A>C p.N206T (on ENST00000473539 / NM_001004196.3; = p.N181T on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV59862165; called by muse, mutect2, varscan2
- CD247 | c.341T>C p.L114P (on ENST00000362089 / NM_198053.3; = p.L113P on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62976934; called by muse, mutect2, varscan2
- CD276 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.72); PolyPhen benign (0.152); catalogued as rs919298201, COSV59202606; called by muse, mutect2, varscan2
- CD2AP | c.307A>T p.N103Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV63759252; called by mutect2, varscan2
- CD33 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51799957; called by muse, mutect2, varscan2
- CD5 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV61717763; called by muse, mutect2, varscan2
- CD5L | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63821091; called by muse, mutect2, varscan2
- CD72 | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV52410193; called by muse, mutect2, varscan2
- CD74 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.63); catalogued as rs773505128, COSV50532067; called by muse, mutect2, varscan2
- CD86 | c.362T>G p.I121S (on ENST00000330540 / NM_175862.5; = p.I115S on NM_006889.4) | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV52605142; called by muse, mutect2, varscan2
- CD8B | c.397A>C p.S133R | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV58925047; called by muse, mutect2
- CD93 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV55663237; called by muse, mutect2, varscan2
- CDC23 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs745709624, COSV67509303; called by muse, mutect2, varscan2
- CDC42BPA | c.525A>C p.E175D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62002321; called by mutect2, varscan2
- CDC42BPG | c.2063T>G p.V688G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61345449; called by muse, mutect2, varscan2
- CDC6 | c.551A>C p.N184T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV52929795; called by muse, mutect2, varscan2
- CDCA7 | c.562C>T p.L188F (on ENST00000347703 / NM_145810.3; = p.L267F on NM_031942.5) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as COSV60719842; called by muse, mutect2, varscan2
- CDCP1 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV56103694; called by muse, mutect2, varscan2
- CDCP1 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 113/194 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs754165008, COSV56103701; called by muse, mutect2, varscan2
- CDCP1 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 106/161 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV56103710; called by muse, mutect2, varscan2
- CDCP2 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as rs1557708028, COSV61282523; called by muse, mutect2, varscan2
- CDH10 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT tolerated (0.52); PolyPhen benign (0.285); catalogued as COSV52570072; called by muse, mutect2, varscan2
- CDH13 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51791284; called by muse, mutect2, varscan2
- CDH19 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as rs745449305, COSV50954397; called by muse, mutect2, varscan2
- CDH2 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs150313483; called by muse, mutect2, varscan2
- CDH26 | c.562T>G p.L188V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as COSV54842693; called by muse, mutect2, varscan2
- CDH4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375893301; called by muse, mutect2, varscan2
- CDH6 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 112/160 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV54064326; called by muse, varscan2
- CDH9 | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.433); catalogued as COSV50252424; called by muse, varscan2
- CDH9 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 190/253 reads (75%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as rs199818706, COSV50252474; called by muse, mutect2, varscan2
- CDK14 | c.1155G>A p.K385= (on ENST00000380050 / NM_001287135.2; = p.K367= on NM_012395.3) | Splice Region (SNP) | VAF 106/198 reads (54%) | catalogued as rs1369783458, COSV56024014, COSV56030355, COSV56056025; called by muse, mutect2, varscan2
- CDK18 | c.818A>C p.K273T (on ENST00000506784 / NM_212503.3; = p.K243T on NM_002596.4) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV63726674; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5120C>T p.P1707L | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs532418421, COSV62571915, COSV62574531; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3295C>T p.Q1099* | Nonsense Mutation (SNP) | VAF 40/60 reads (67%) | catalogued as COSV62572114; called by muse, mutect2, varscan2
- CDK9 | c.503T>C p.F168S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64723359; called by muse, mutect2
- CDR2 | c.449A>C p.D150A | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51675228; called by muse, mutect2
- CDS2 | c.511T>C p.F171L | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV66895283; called by muse, mutect2, varscan2
- CDSN | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs1333991970, COSV52537240; called by muse, mutect2, varscan2
- CEACAM5 | c.535T>C p.W179R | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.484); catalogued as COSV55750691; called by muse, mutect2, varscan2
- CEACAM5 | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55750698; called by muse, mutect2, varscan2
- CEACAM7 | c.221A>C p.H74P | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV50072483; called by muse, mutect2, varscan2
- CEBPZ | c.2948G>A p.G983D | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99305115; called by muse, mutect2, varscan2
- CEBPZ | c.2947G>A p.G983S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV99305118; called by muse, mutect2, varscan2
- CECR2 | c.1928C>A p.P643H (on ENST00000342247 / NM_001290047.2; = p.P460H on NM_001290046.1) | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV99377427; called by muse, mutect2, varscan2
- CECR2 | c.3289G>A p.E1097K (on ENST00000342247 / NM_001290047.2; = p.E913K on NM_001290046.1) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as rs752465426, COSV52836171; called by muse, mutect2, varscan2
- CELF5 | c.334T>G p.L112V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV53010261; called by muse, mutect2
- CELSR1 | c.6361C>T p.R2121C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs575259420, CM127428, COSV53083593; called by muse, mutect2, varscan2
- CELSR2 | c.3803C>T p.P1268L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV54766779; called by muse, mutect2, varscan2
- CEMIP2 | c.694T>G p.L232V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV65485620; called by muse, mutect2, varscan2
- CENPE | c.7081C>T p.P2361S | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54376146; called by muse, mutect2, varscan2
- CENPF | c.6277T>G p.L2093V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65272685; called by muse, mutect2, varscan2
- CEP104 | c.2267T>C p.F756S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1205625419, COSV65516153; called by muse, mutect2, varscan2
- CEP126 | c.3215C>T p.S1072F | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54821704; called by muse, mutect2, varscan2
- CEP131 | c.1901T>G p.I634S (on ENST00000269392 / NM_001319228.2; = p.I631S on NM_014984.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53950624; called by muse, mutect2
- CEP135 | c.1028A>G p.E343G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57258058; called by muse, mutect2, varscan2
- CEP152 | c.1775A>G p.E592G | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV57856663; called by muse, mutect2, varscan2
- CEP250 | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs763406705, COSV61168241; called by muse, mutect2, varscan2
- CEP250 | c.7090A>C p.T2364P | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV61168246; called by muse, mutect2, varscan2
- CEP350 | c.1511T>C p.L504P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.369); catalogued as COSV62598771; called by muse, mutect2, varscan2
- CEP350 | c.4664C>T p.P1555L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1179828630, COSV62598779; called by muse, mutect2, varscan2
- CEP72 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.225); catalogued as COSV53790258; called by muse, mutect2, varscan2
- CEP85 | c.391A>G p.R131G | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as rs1419946982, COSV53327073; called by muse, mutect2, varscan2
- CER1 | c.196A>T p.T66S | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV66602908; called by muse, mutect2
- CERS3 | c.833T>G p.V278G | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs557826222, COSV52564991; called by muse, mutect2, varscan2
- CERT1 | c.847C>T p.H283Y (on ENST00000405807 / NM_001130105.1; = p.H155Y on NM_005713.3) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV54655482; called by muse, mutect2, varscan2
- CFAP251 | c.1677A>C p.E559D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV56607907; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.034); catalogued as rs373620410, COSV55828405; called by muse, mutect2, varscan2
- CFAP57 | c.969G>A p.R323= | Splice Region (SNP) | VAF 31/98 reads (32%) | catalogued as COSV65263585; called by muse, mutect2, varscan2
- CFAP58 | c.1298A>G p.K433R | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV100458729, COSV57211279; called by muse, mutect2
- CFAP74 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV54564615; called by muse, mutect2, varscan2
- CFH | c.221T>G p.L74R | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV62776277, COSV62779025; called by muse, mutect2, varscan2
- CFHR5 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.8); PolyPhen benign (0.105); catalogued as COSV56818067; called by muse, mutect2, varscan2
- CFHR5 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56818085; called by muse, mutect2, varscan2
- CFHR5 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56817511, COSV56818106; called by muse, mutect2, varscan2
- CFI | c.658+2T>G p.X220_splice | Splice Site (SNP) | VAF 21/92 reads (23%) | catalogued as COSV67097724, COSV67097855; called by muse, mutect2, varscan2
- CFTR | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV50041041; called by muse, varscan2
- CFTR | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 43/94 reads (46%) | catalogued as CM941971, COSV50041069; called by muse, mutect2, varscan2
- CFTR | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397508211, CM970276, COSV50041123; called by muse, mutect2, varscan2
- CFTR | c.4273G>A p.D1425N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs867990936, COSV50041151, COSV50113324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGB5 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100031969; called by mutect2, varscan2
- CGN | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as COSV54967968; called by muse, mutect2, varscan2
- CHAF1A | c.593A>C p.D198A | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.015); catalogued as COSV56670303; called by muse, mutect2, varscan2
- CHAMP1 | c.1323A>C p.K441N | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63521735; called by muse, mutect2
- CHD1 | c.3710A>G p.Q1237R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52337179; called by muse, mutect2, varscan2
- CHD1L | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63612731; called by muse, mutect2, varscan2
- CHD4 | c.2605C>T p.Q869* (on ENST00000357008 / NM_001363606.2; = p.Q882* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 43/85 reads (51%) | catalogued as COSV58894848; called by muse, mutect2, varscan2
- CHD5 | c.4450G>A p.E1484K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV52407538; called by muse, mutect2
- CHD6 | c.773A>T p.D258V | Missense Mutation (SNP) | VAF 238/533 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58553893; called by muse, mutect2, varscan2
- CHD8 | c.3292C>T p.P1098S (on ENST00000646647 / NM_001170629.2; = p.P819S on NM_020920.4) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67869673; called by muse, mutect2, varscan2
- CHD8 | c.2437G>A p.E813K (on ENST00000646647 / NM_001170629.2; = p.E534K on NM_020920.4) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67869678; called by muse, mutect2, varscan2
- CHDH | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1399914263, COSV59455876; called by muse, mutect2
- CHGA | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53662365; called by muse, mutect2, varscan2
- CHL1 | c.829A>C p.I277L (on ENST00000397491 / NM_001253387.1; = p.I293L on NM_006614.4) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV56586572; called by mutect2, varscan2
- CHRD | c.700-2A>C p.X234_splice | Splice Site (SNP) | VAF 47/566 reads (8%) | catalogued as COSV52605473; called by muse, mutect2
- CHRM2 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.574); catalogued as COSV57765434, COSV57776331; called by muse, mutect2, varscan2
- CHRM3 | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV55080292; called by muse, mutect2, varscan2
- CHRM3 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.158); catalogued as COSV55080302; called by muse, mutect2, varscan2
- CHRNA1 | c.589G>A p.D197N (on ENST00000261007 / NM_001039523.3; = p.D172N on NM_000079.4) | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs1232135247, COSV53681590; called by muse, mutect2, varscan2
- CHRNA10 | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV51702881; called by muse, mutect2, varscan2
- CHRNA9 | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV59573513; called by muse, mutect2, varscan2
- CHRNA9 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 52/157 reads (33%) | catalogued as COSV59573522; called by muse, mutect2, varscan2
- CHRNB3 | c.308T>G p.I103S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51493213; called by muse, mutect2, varscan2
- CHRNB4 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 46/46 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as rs573139426, COSV55714613; called by muse, mutect2, varscan2
- CIC | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1334267003, COSV50547398; called by muse, mutect2, varscan2
- CIITA | c.1454G>T p.S485I | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as COSV60854063; called by muse, mutect2, varscan2
- CIPC | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.708); catalogued as COSV62376673; called by muse, mutect2, varscan2
- CIPC | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62376676; called by muse, varscan2
- CIPC | c.1025A>G p.Q342R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs373322491; called by muse, varscan2
- CIT | c.3806A>C p.K1269T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as COSV55859877; called by muse, mutect2, varscan2
- CIT | c.3446A>C p.K1149T | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs1398089791, COSV55859892; called by muse, mutect2, varscan2
- CKM | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV55531815; called by muse, mutect2, varscan2
- CLCA2 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV65286143; called by muse, mutect2, varscan2
- CLCA4 | c.213T>G p.F71L | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV55366076; called by muse, mutect2
- CLCN1 | c.1367T>G p.V456G | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100578687, COSV58367381; called by muse, mutect2, varscan2
- CLCN1 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58367388; called by muse, mutect2, varscan2
- CLCNKA | c.1751G>A p.S584N | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs778093102, COSV58890398; called by muse, mutect2, varscan2
- CLDN10 | c.674A>C p.N225T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV54823294; called by muse, mutect2
- CLDN15 | c.32T>A p.F11Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56190873; called by muse, mutect2, varscan2
- CLEC2L | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.345); catalogued as COSV70691013; called by muse, mutect2, varscan2
- CLEC4M | c.747A>C p.Q249H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV50216765; called by muse, mutect2, varscan2
- CLIC1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV101007454; called by muse, mutect2, varscan2
- CLIC1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV101007455; called by muse, mutect2, varscan2
- CLMN | c.2177T>G p.L726R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV54178927, COSV54180366; called by muse, mutect2, varscan2
- CLOCK | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV59400426; called by muse, mutect2, varscan2
- CLPTM1 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1333156934, COSV61610976; called by muse, mutect2, varscan2
- CLPTM1 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs138129932, COSV61611015; called by muse, mutect2, varscan2
- CLSPN | c.44A>T p.D15V | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV52046798; called by muse, mutect2, varscan2
- CLSTN1 | c.1871C>T p.T624I (on ENST00000377298 / NM_001009566.3; = p.T614I on NM_014944.4) | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV63646552; called by muse, mutect2, varscan2
- CLTRN | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV66711641; called by muse, mutect2, varscan2
- CLVS2 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.16); PolyPhen benign (0.345); catalogued as COSV51558807; called by muse, varscan2
- CLVS2 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as COSV51558822; called by muse, mutect2, varscan2
- CMAS | c.630A>C p.E210D | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV57555976; called by muse, mutect2, varscan2
- CMSS1 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV70435583; called by muse, mutect2, varscan2
- CMTM5 | c.659G>A p.G220E (on ENST00000339180 / NM_001288746.2; = p.G153E on NM_138460.3) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV59304814; called by muse, mutect2, varscan2
- CMYA5 | c.6505G>A p.E2169K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as COSV71404083; called by muse, mutect2, varscan2
- CMYA5 | c.6872A>C p.K2291T | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV71404084; called by muse, mutect2, varscan2
- CMYA5 | c.7307C>T p.P2436L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV101484413, COSV71404085; called by muse, mutect2, varscan2
- CMYA5 | c.9036A>C p.K3012N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV101484385, COSV71404086; called by muse, mutect2, varscan2
- CNBD2 | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as rs556064819, COSV62586327; called by muse, mutect2, varscan2
- CNBD2 | c.1337G>A p.G446E (on ENST00000373973 / NM_001365709.1; = p.G442E on NM_080834.4) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62586331; called by muse, mutect2, varscan2
- CNGA1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.073); catalogued as COSV62052962; called by muse, mutect2, varscan2
- CNGA2 | c.1163A>C p.K388T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV61703198; called by muse, mutect2, varscan2
- CNGB3 | c.326A>C p.E109A | Missense Mutation (SNP) | VAF 109/209 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.257); catalogued as COSV60684645; called by muse, mutect2, varscan2
- CNMD | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765293200, COSV60129568; called by muse, mutect2, varscan2
- CNN1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs748140771, COSV52955266, COSV52956274; called by muse, mutect2, varscan2
- CNNM1 | c.2770A>C p.T924P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV63200221; called by muse, mutect2, varscan2
- CNTLN | c.3158A>G p.D1053G | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV52066350; called by muse, mutect2, varscan2
- CNTN4 | c.460A>T p.S154C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.585); catalogued as COSV61867840, COSV61877283; called by muse, mutect2, varscan2
- CNTN4 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV61867845; called by muse, mutect2, varscan2
- CNTN4 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1393573209, COSV61867862; called by muse, mutect2, varscan2
- CNTN5 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs942238616, COSV54281179; called by muse, mutect2, varscan2
- CNTN5 | c.3032T>G p.V1011G | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54281203; called by muse, mutect2, varscan2
- CNTNAP2 | c.3095G>A p.R1032K | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs758650857, COSV62145712, COSV62209746; called by muse, mutect2, varscan2
- CNTNAP2 | c.3730C>T p.P1244S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV62145718; called by muse, mutect2
- CNTNAP5 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.881); catalogued as rs1301592326, COSV70472897; called by muse, mutect2
- CNTNAP5 | c.3184G>C p.D1062H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as COSV70472913; called by muse, mutect2, varscan2
- CNTRL | c.3250A>C p.M1084L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV53043207; called by muse, mutect2, varscan2
- COASY | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV99888298; called by muse, mutect2, varscan2
- COASY | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as COSV99888299; called by muse, mutect2, varscan2
- COBL | c.1845A>C p.L615F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.122); catalogued as COSV54337951; called by muse, mutect2
- COBLL1 | c.1795G>A p.E599K (on ENST00000392717; = p.E561K on NM_014900.5) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV52063102; called by muse, mutect2, varscan2
- COBLL1 | c.1534G>A p.E512K (on ENST00000392717; = p.E474K on NM_014900.5) | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.409); catalogued as COSV52063117; called by muse, mutect2, varscan2
- COL11A1 | c.4894G>A p.G1632R | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as COSV62172983; called by muse, mutect2, varscan2
- COL11A1 | c.4729G>A p.E1577K | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV62172988; called by muse, mutect2, varscan2
- COL11A1 | c.4205G>A p.G1402E | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62172996; called by muse, mutect2, varscan2
- COL11A1 | c.3008G>A p.G1003E | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62173003; called by muse, mutect2, varscan2
- COL11A2 | c.3701G>A p.G1234E (on ENST00000341947 / NM_080680.3; = p.G1127E on NM_080679.2) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59493576; called by muse, mutect2, varscan2
- COL14A1 | c.4616G>A p.G1539E | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52847271; called by muse, mutect2, varscan2
- COL14A1 | c.5078-1G>A p.X1693_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as COSV52847277; called by muse, mutect2, varscan2
- COL16A1 | c.2965A>C p.N989H | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV54701152; called by muse, mutect2, varscan2
- COL18A1 | c.1637G>A p.G546E (on ENST00000359759 / NM_130444.3; = p.G311E on NM_030582.4) | Missense Mutation (SNP) | VAF 69/75 reads (92%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as rs368606628; called by muse, mutect2, varscan2
- COL19A1 | c.390G>A p.Q130= | Splice Region (SNP) | VAF 41/42 reads (98%) | catalogued as COSV59565401; called by muse, mutect2, varscan2
- COL19A1 | c.1037G>A p.G346E | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59565422; called by muse, mutect2, varscan2
- COL1A1 | c.3816A>G p.G1272= | Splice Region (SNP) | VAF 14/70 reads (20%) | catalogued as COSV56802522; called by muse, mutect2, varscan2
- COL1A1 | c.1983G>A p.Q661= | Splice Region (SNP) | VAF 5/14 reads (36%) | catalogued as rs1454079919, CP044508, COSV56802544; called by muse, mutect2, varscan2
- COL1A1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV56802551; called by muse, mutect2, varscan2
- COL1A2 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs765116624, COSV51952925; called by muse, mutect2, varscan2
- COL21A1 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55153632; called by muse, varscan2
- COL21A1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1378533564, COSV55153658; called by muse, mutect2
- COL21A1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs267601087, COSV55152247; called by muse, mutect2, varscan2
- COL22A1 | c.4505C>A p.P1502Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57323247; called by muse, mutect2, varscan2
- COL24A1 | c.2852G>A p.G951E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65301838; called by muse, mutect2, varscan2
- COL3A1 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58581957; called by muse, mutect2, varscan2
- COL3A1 | c.3568C>T p.P1190S | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV58581994; called by muse, mutect2, varscan2
- COL4A2 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV64624829; called by muse, mutect2, varscan2
- COL4A4 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61629553; called by muse, mutect2, varscan2
- COL4A5 | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV60356156; called by muse, mutect2, varscan2
- COL4A6 | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57859380; called by muse, mutect2, varscan2
- COL5A1 | c.2386-1G>A p.X796_splice | Splice Site (SNP) | VAF 69/111 reads (62%) | catalogued as CS093851, COSV65665036; called by muse, mutect2, varscan2
- COL5A1 | c.2846G>A p.G949E | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65665040; called by muse, mutect2, varscan2
- COL5A3 | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53406258; called by muse, mutect2, varscan2
- COL5A3 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV53406265; called by muse, mutect2, varscan2
- COL6A2 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55998772; called by muse, mutect2, varscan2
- COL6A2 | c.3035A>C p.D1012A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV52423176; called by muse, mutect2, varscan2
- COL6A3 | c.6778C>T p.P2260S | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); catalogued as COSV55079795; called by muse, mutect2, varscan2
- COL6A3 | c.6076G>A p.E2026K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs770907851, COSV55109826; called by muse, mutect2, varscan2
- COL6A6 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 48/51 reads (94%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100650077; called by muse, mutect2, varscan2
- COL6A6 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100650078; called by muse, mutect2, varscan2
- COL6A6 | c.1760A>G p.E587G | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV62017733, COSV62030387; called by muse, mutect2, varscan2
- COL6A6 | c.1907A>G p.E636G | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV62017744; called by muse, mutect2, varscan2
- COL6A6 | c.4463G>A p.G1488E | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62017757; called by muse, mutect2, varscan2
- COL8A1 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53729448; called by muse, mutect2, varscan2
- COL8A2 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV57440639; called by muse, mutect2, varscan2
- COLEC12 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as COSV68368493, COSV68368626; called by muse, mutect2, varscan2
- COMMD3 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163843987, COSV100936354; called by muse, mutect2, varscan2
- COPG1 | c.1569A>C p.E523D | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59112366; called by muse, mutect2, varscan2
- CORIN | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56686154; called by muse, varscan2
- CORO2A | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59661967; called by muse, mutect2, varscan2
- COX19 | c.241T>A p.L81M | Missense Mutation (SNP) | VAF 69/471 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV59937280; called by muse, mutect2, varscan2
- COX8C | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV56373948, COSV56376243; called by muse, mutect2, varscan2
- CPA5 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.735); catalogued as COSV62568765; called by muse, varscan2
- CPNE3 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV52204019; called by muse, mutect2, varscan2
- CPS1 | c.3697G>T p.A1233S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.338); catalogued as COSV99242545; called by muse, mutect2, varscan2
- CPSF1 | c.3095A>C p.K1032T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV58232194; called by muse, mutect2, varscan2
- CPT1A | c.2020C>A p.L674I | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs75908421, COSV55752848, COSV55755069; called by muse, mutect2, varscan2
- CPT1A | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.791); catalogued as COSV55752860; called by muse, mutect2, varscan2
- CPT1A | c.181A>C p.S61R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV55752870; called by muse, mutect2, varscan2
- CPT1C | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201458521, COSV54917581; called by muse, mutect2, varscan2
- CR1 | c.1051C>T p.P351S (on ENST00000367051; = p.P801S on NM_000651.6) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100887473; called by mutect2, varscan2
- CRB1 | c.1649A>T p.N550I | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV66328651; called by muse, mutect2, varscan2
- CRB1 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as rs564754426, COSV66328611; called by muse, mutect2, varscan2
- CRB1 | c.3376C>T p.L1126F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs149390998, COSV66328659; called by muse, mutect2, varscan2
- CRB2 | c.892T>G p.F298V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV63501706; called by muse, mutect2, varscan2
- CRCT1 | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | PolyPhen possibly damaging (0.663); catalogued as COSV57499900; called by muse, mutect2, varscan2
- CRNKL1 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs1249662730, COSV55619221; called by muse, mutect2, varscan2
- CRNKL1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs763086392, COSV55619227, COSV99844357; called by muse, mutect2, varscan2
- CRNN | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 195/403 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV55120764; called by muse, mutect2, varscan2
- CRTAP | c.161A>T p.K54M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.295); catalogued as COSV58012967; called by muse, mutect2, varscan2
- CRTC1 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 219/468 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV58716418; called by muse, mutect2, varscan2
- CRTC2 | c.1428A>C p.K476N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.991); catalogued as COSV57841033; called by muse, mutect2, varscan2
- CRTC2 | c.1058A>G p.Q353R | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.778); catalogued as COSV57841046; called by muse, mutect2, varscan2
- CRX | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 121/261 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.597); catalogued as rs781610314, COSV55757031; called by muse, mutect2, varscan2
- CSF1 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.575); catalogued as rs775031771, COSV60031932; called by muse, mutect2, varscan2
- CSF1R | c.907T>G p.L303V | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53828543; called by muse, mutect2, varscan2
- CSMD1 | c.10333G>A p.E3445K (on ENST00000520002; = p.E3444K on NM_033225.6) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as rs779091673, COSV59282113, COSV59380793; called by muse, varscan2
- CSMD1 | c.5816C>T p.S1939F (on ENST00000520002; = p.S1938F on NM_033225.6) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs930117621, COSV59282134; called by muse, mutect2, varscan2
- CSMD1 | c.3142G>A p.D1048N (on ENST00000520002; = p.D1047N on NM_033225.6) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59282193; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, mutect2, varscan2
- CSMD1 | c.1124C>T p.S375L (on ENST00000520002; = p.S374L on NM_033225.6) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs762593887, COSV68165271; called by muse, mutect2, varscan2
- CSMD2 | c.9161G>A p.G3054E | Missense Mutation (SNP) | VAF 67/111 reads (60%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as rs867595146, COSV53878837; called by muse, mutect2, varscan2
- CSMD2 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256151793, COSV53879518, COSV99596900; called by muse, mutect2, varscan2
- CSMD2 | c.1595G>A p.R532K | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV53879543; called by muse, mutect2, varscan2
- CSMD2 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.313); catalogued as rs1475022954, COSV53879578; called by muse, mutect2, varscan2
- CSMD3 | c.9899G>A p.G3300E (on ENST00000297405 / NM_001363185.1; = p.G3131E on NM_052900.3) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52103513; called by muse, mutect2, varscan2
- CSMD3 | c.3362T>C p.L1121S (on ENST00000297405 / NM_001363185.1; = p.L1017S on NM_052900.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV52103543; called by muse, mutect2, varscan2
- CSMD3 | c.3284G>A p.W1095* (on ENST00000297405 / NM_001363185.1; = p.W991* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 21/28 reads (75%) | catalogued as COSV52093583; called by muse, mutect2, varscan2
- CSMD3 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1444297700, COSV52103573; called by muse, mutect2, varscan2
- CSNK1A1L | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV65789464; called by muse, mutect2, varscan2
- CSNK1D | c.444C>G p.I148M | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53922978; called by muse, mutect2, varscan2
- CSNK2A1 | c.863A>C p.E288A | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV53933655; called by muse, mutect2, varscan2
- CST6 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56409011; called by muse, mutect2, varscan2
- CTAGE6 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 4/7 reads (57%) | catalogued as COSV69918725; called by mutect2, varscan2
- CTDSPL | c.585A>T p.E195D (on ENST00000273179 / NM_001008392.2; = p.E184D on NM_005808.3) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as COSV99828601; called by muse, mutect2, varscan2
- CTNNB1 | c.2285T>C p.L762P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV62689732; called by muse, mutect2, varscan2
- CTNS | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99251115; called by muse, mutect2, varscan2
- CTNS | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs567999441, COSV99251119; called by muse, mutect2, varscan2
- CTPS1 | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV65451763; called by muse, mutect2, varscan2
- CTSA | c.1132A>C p.N378H | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV51940626; called by muse, mutect2, varscan2
- CTSE | c.1201C>T p.P401S (on ENST00000360218; = p.P396S on NM_001910.4) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63059711; called by muse, mutect2, varscan2
- CTSG | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT tolerated (0.45); PolyPhen benign (0.051); catalogued as rs759013839, COSV53534623; called by muse, mutect2, varscan2
- CTSV | c.68A>G p.Q23R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99414344; called by muse, mutect2
- CUBN | c.7889T>G p.F2630C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as COSV64707867; called by muse, mutect2
- CUL1 | c.2000C>T p.T667I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV57386745; called by muse, mutect2, varscan2
- CUL3 | c.625T>A p.F209I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1418778821, COSV52361421; called by muse, mutect2, varscan2
- CUL7 | c.2281A>T p.K761* | Nonsense Mutation (SNP) | VAF 45/216 reads (21%) | catalogued as COSV54813105; called by muse, mutect2, varscan2
- CUX1 | c.2744C>T p.P915L | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs1164065810, COSV52891198; called by muse, mutect2, varscan2
- CWF19L1 | c.1486A>G p.S496G | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV62498948; called by muse, mutect2, varscan2
- CX3CL1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 59/66 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1328367528, COSV50055451; called by muse, mutect2, varscan2
- CXADR | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53027815; called by muse, mutect2, varscan2
- CYB5R3 | c.629A>C p.N210T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61544893; called by muse, mutect2, varscan2
- CYB5R4 | c.460A>G p.S154G | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV63750082; called by muse, mutect2, varscan2
- CYBRD1 | c.532T>G p.L178V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58425862; called by muse, mutect2, varscan2
4,301 further variants in this file (2,713 protein-altering or splice-affecting, 1,477 silent, 111 other) are not listed here.
